Gene-level copy-number profile of tumor specimen TCGA-P7-A5NX-01A from TCGA case TCGA-P7-A5NX, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 78.0 years (28,497 days).
Specimen TCGA-P7-A5NX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e5ce887c-d09e-4b89-ae35-0fe7daec7228.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-P7-A5NX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/0b764ffe-64d4-41d0-abb6-39b84004ee8f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 2: 3,295; copy number 3: 3,105; copy number 4: 49,126; copy number 5: 592; copy number 6: 2,280.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:112,967–186,136, 5 genes (within-gene range 0–2): AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
